Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A4YT, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A4YT-01A (Primary Tumor).

Patient: XXX PESEL: XXX Age: Gender: M

Examination result No.

Unit in charge: ()
Physician in charge:
Clinical diagnosis (suspicion): **Stomach carcinoma.**
Date of admission: (urgency: Standard)

Material:

1) Material: stomach, Method of collection: Total organ resection

Histopathology Diagnosis: Examination performed on:

Stomach adenocarcinoma (G2, pT2, pNO). (8140/3 T-63000)

Macroscopic description:

Specimen consisting of the stomach, having been cut out along the greater curvature, sized 19.7 x 17.4 cm with the omentum sized 25 x 7 cm. Tumour sized 6.4 x 5.8 x 1.4 cm in the cardia region of the lesser curvature.

Distance from the proximal end: 0.9 cm, from distal end: 12.2 cm.

Microscopic description:

Adenocarcinoma tubulopapillare partim mucinosum G3 ventriculi. Intestinal type acc. to
Tumour penetrates the stomach muscle membrane fat tissue (pT2). Incision lines, omentum and lymph nodes (14) – free of neoplastic lesions.

Assistant: Pathologist: Edited by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

ICD-0-3
adenocarcinoma, tubular 8140/3
Site: Stomach, cardia, NOS C16.0
pw
11/4/12

ICDAA Discrepancy		X
Simultaneous Primary Sites		X
Site (circle):	QUADRANT	DISQUANT

11/4/12

Source: NCI Genomic Data Commons file 005fc6c9-005e-45d5-84c5-96cc2abe48ef (TCGA-D7-A4YT.1CD7E730-70D9-40A2-9711-329D807FDF61.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).